Somatic mutation profile of tumor specimen TCGA-RQ-A6JB-01A (aliquot TCGA-RQ-A6JB-01A-11D-A31X-10) from TCGA case TCGA-RQ-A6JB, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Primary diffuse large B-cell lymphoma of the CNS; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 62.6 years (22,859 days).
Specimen TCGA-RQ-A6JB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28d6bebe-0662-44f1-b9f1-5de176dc9ca8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RQ-A6JB-10A (Blood Derived Normal), aliquot TCGA-RQ-A6JB-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ce86398-f739-4670-9dd1-60afda0be332

The open-access MAF lists 95 somatic variants for this specimen: 74 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 63, Silent 21, In Frame Del 3, Nonsense Mutation 2, Frame Shift Ins 2, Nonstop Mutation 1, Splice Site 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAT3 | c.1847_1849del p.E616del | In Frame Del (DEL) | VAF 22/72 reads (31%) | hotspot (GDC flag); called by pindel, varscan2
- AC068580.4 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs754680487, COSV99362296; called by muse, mutect2, varscan2
- AHCYL2 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs746525069, COSV100273212; called by muse, mutect2, varscan2
- APBA3 | c.1639A>C p.T547P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99515913; called by muse, mutect2, varscan2
- APOA1 | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99369197; called by muse, mutect2, varscan2
- B2M | c.161A>T p.D54V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV100837605; called by muse, varscan2
- CACNA2D4 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs772210135, COSV99765371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN7 | c.2016T>A p.Y672* | Nonsense Mutation (SNP) | VAF 86/234 reads (37%) | catalogued as COSV99512676; called by muse, mutect2, varscan2
- CAVIN4 | c.661A>T p.I221F | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.318); catalogued as COSV100293190; called by muse, mutect2, varscan2
- CIDEB | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99350587; called by muse, mutect2, varscan2
- CISD2 | c.298A>T p.R100W | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99913568; called by muse, mutect2, varscan2
- COL8A1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.006); catalogued as COSV99657432; called by muse, mutect2, varscan2
- CRISP3 | c.262G>T p.A88S (on ENST00000371159 / NM_001368123.1; = p.A70S on NM_006061.4) | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99538805; called by muse, mutect2, varscan2
- CYP2C8 | c.1072T>C p.Y358H | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV100987904; called by muse, mutect2, varscan2
- DACH2 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1231178580, COSV100912904; called by muse, mutect2, varscan2
- DCAF1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.271); catalogued as COSV100244244; called by muse, mutect2, varscan2
- DNAH17 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.314); catalogued as COSV101101834; called by muse, mutect2, varscan2
- EFHD1 | c.720G>T p.*240Yext*3 | Nonstop Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99898382; called by muse, varscan2
- EFNB1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV52662524; called by muse, mutect2, varscan2
- EIPR1 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0.061); catalogued as rs148621025; called by muse, mutect2, varscan2
- EPHX2 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100994530; called by muse, mutect2, varscan2
- EPYC | c.622del p.E208Nfs*6 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | catalogued as COSV99664577; called by mutect2, varscan2
- FAM81B | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51981429, COSV51987605; called by muse, mutect2, varscan2
- GPN3 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99959789; called by muse, mutect2, varscan2
- H3-5 | c.44A>C p.K15T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV61187159; called by mutect2, varscan2
- HDX | c.1783A>T p.N595Y | Missense Mutation (SNP) | VAF 106/358 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99946988; called by muse, varscan2
- HELT | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100132856; called by muse, mutect2, varscan2
- HLA-A | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 103/170 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100954332, COSV65144330; called by muse, varscan2
- HSF1 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100183979; called by muse, mutect2, varscan2
- IGHV2-70 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs371561110; called by muse, varscan2
- IGLV3-1 | c.133A>T p.K45* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as rs187892119; called by muse, varscan2
- IGLV3-1 | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1426539348; called by muse, varscan2
- IRF8 | c.163T>G p.S55A | Missense Mutation (SNP) | VAF 65/83 reads (78%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV51897668; called by muse, mutect2, varscan2
- MARCKSL1 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100269533; called by muse, mutect2, varscan2
- MINAR1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs760038690, COSV59581806; called by muse, mutect2, varscan2
- MOS | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100322787; called by muse, mutect2, varscan2
- MYD88 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.52); PolyPhen benign (0.139); catalogued as COSV100085975; called by muse, mutect2, varscan2
- NTM | c.337T>A p.Y113N | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100868041; called by muse, mutect2, varscan2
- NUDT5 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.65); catalogued as rs763726609, COSV100421987; called by muse, mutect2, varscan2
- OR10C1 | c.213G>C p.E71D (on ENST00000622521; = p.E69D on NM_013941.3) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as rs977356543, COSV101010777; called by muse, mutect2, varscan2
- P2RY4 | c.899G>A p.C300Y | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100996999; called by muse, mutect2, varscan2
- PDHA2 | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174570998, COSV99756694; called by muse, mutect2, varscan2
- PLK3 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59501184; called by muse, varscan2
- POLR2A | c.4772C>T p.P1591L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs774093039; called by muse, mutect2, varscan2
- PPP2CA | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs772521505, COSV99196031; called by muse, varscan2
- PRKDC | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV100039432; called by muse, varscan2
- PTPN3 | c.5C>G p.T2S | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV99355558; called by muse, mutect2, varscan2
- RBM39 | c.1398C>G p.D466E (on ENST00000253363 / NM_001323424.2; = p.D460E on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99488386; called by muse, mutect2, varscan2
- RNASE4 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1241153030, COSV59012355; called by muse, mutect2, varscan2
- S1PR2 | c.787T>C p.S263P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as COSV100495288; called by muse, mutect2, varscan2
- S1PR2 | c.786C>A p.H262Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100495291; called by muse, mutect2, varscan2
- SALL4 | c.826A>C p.S276R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV99409345; called by muse, mutect2, varscan2
- SBSPON | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs757345283, COSV52078369; called by muse, mutect2, varscan2
- SLC25A37 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1288218982, COSV51565355, COSV99263895; called by muse, mutect2, varscan2
- SPIDR | c.1784A>C p.H595P | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV99854603; called by muse, mutect2, varscan2
- STARD13 | c.2993A>T p.Q998L (on ENST00000336934 / NM_001243476.3; = p.Q880L on NM_052851.3) | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as COSV99715643; called by muse, mutect2, varscan2
- TDRD6 | c.6261+2T>C p.X2087_splice | Splice Site (SNP) | VAF 46/121 reads (38%) | catalogued as COSV100287383; called by muse, mutect2, varscan2
- THOC2 | c.442T>G p.S148A | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV99833037; called by muse, mutect2, varscan2
- TMEM177 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs758353670, COSV55609469; called by muse, mutect2, varscan2
- TNN | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV99511548; called by muse, mutect2, varscan2
- TSPAN31 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99222692; called by muse, mutect2, varscan2
- UNC93B1 | c.1336A>T p.S446C | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99916313; called by muse, mutect2, varscan2
- USH2A | c.5435T>G p.I1812R | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as COSV100232156; called by muse, mutect2, varscan2
- ZHX2 | c.2456T>C p.V819A | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV100072797; called by muse, mutect2, varscan2
- ZNF547 | c.1153A>G p.K385E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV99987827; called by muse, mutect2, varscan2
- ZNF547 | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV56582274, COSV99987831; called by muse, mutect2, varscan2
- ZNF709 | c.23A>G p.D8G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101172136; called by muse, mutect2, varscan2
- ZWINT | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100571493; called by muse, mutect2, varscan2
- AP1G1 | c.229dup p.Q77Pfs*19 | Frame Shift Ins (INS) | VAF 91/247 reads (37%) | called by mutect2, varscan2
- CTDSPL2 | c.896_897dup p.H300Cfs*5 | Frame Shift Ins (INS) | VAF 36/70 reads (51%) | called by mutect2, varscan2
- HMGB1 | c.55_57dup p.F19dup | In Frame Ins (INS) | VAF 10/31 reads (32%) | called by pindel, varscan2
- PURA | c.491_532del p.R164_G177del | In Frame Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel
- SMC6 | c.2648_2656del p.A883_H885del | In Frame Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- TCTE1 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, mutect2
- ADAM22 | c.1182C>T p.C394= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs1426450191, COSV99715287; called by muse, mutect2, varscan2
- ATOH1 | c.1050G>A p.S350= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100024470; called by muse, mutect2, varscan2
- CDH2 | c.906G>A p.G302= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as rs1345941740, COSV52280389, COSV52296763; called by muse, mutect2, varscan2
- CDKL5 | c.3054C>G p.L1018= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV101183759; called by muse, mutect2, varscan2
- FAAH2 | c.1533G>T p.L511= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV100887216; called by muse, mutect2, varscan2
- FCER1G | c.133C>A p.R45= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV57154228, COSV99248145; called by muse, mutect2, varscan2
- IGKV3D-11 | c.255T>C p.S85= | Silent (SNP) | VAF 74/193 reads (38%) | called by muse, mutect2, varscan2
- ITGAV | c.2571G>A p.E857= | Silent (SNP) | VAF 58/166 reads (35%) | catalogued as COSV99654590; called by muse, mutect2, varscan2
- KALRN | c.3798C>T p.D1266= | Silent (SNP) | VAF 47/161 reads (29%) | catalogued as rs770766778, COSV53753688; called by muse, mutect2, varscan2
- MAGEC1 | c.2259G>A p.L753= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99595306; called by muse, mutect2, varscan2
- MEGF9 | c.1524A>G p.V508= | Silent (SNP) | VAF 74/196 reads (38%) | catalogued as COSV100879344; called by muse, mutect2, varscan2
- PNPLA6 | c.3015C>T p.V1005= (on ENST00000414982 / NM_001166111.2; = p.V957= on NM_006702.5) | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs572115607, COSV99653359; called by muse, mutect2, varscan2
- RASL12 | c.597C>T p.S199= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs758470678, COSV99584842; called by muse, mutect2, varscan2
- RASSF9 | c.1017C>T p.I339= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as rs1278932361, COSV100771293; called by muse, mutect2, varscan2
- SCNN1A | c.705C>T p.D235= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV99964617; called by muse, mutect2, varscan2
- SI | c.1029A>T p.G343= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100014773; called by muse, mutect2, varscan2
- SYNRG | c.2715C>A p.G905= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- TBX22 | c.120C>T p.G40= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV100960708; called by muse, mutect2, varscan2
- TNIK | c.3297C>T p.V1099= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99456196; called by mutect2, varscan2
- ZEB1 | c.2952C>G p.S984= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV100314018; called by muse, mutect2, varscan2
- ZSCAN20 | c.1090C>T p.L364= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV100792535; called by muse, mutect2, varscan2
